Gene-level copy-number profile of tumor specimen TCGA-BG-A0M6-01A from TCGA case TCGA-BG-A0M6, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 73.0 years (26,666 days).
Specimen TCGA-BG-A0M6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.c2f2f785-e2d3-484d-a2ae-f70446ff12bd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BG-A0M6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0908d230-77cc-4ee0-9a61-8cdce77f8d46

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 886; copy number 2: 16,413; copy number 3: 20,739; copy number 4: 15,767; copy number 5: 2,002; copy number 6: 2,779; copy number 7: 295; copy number 8: 474; copy number 9: 75; copy number 10: 231; copy number 12: 34; copy number 13: 1; copy number 14: 49; copy number 17: 35; copy number 33: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BG-A0M6-01A-31D-A102-01): tumor purity 0.69, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,229 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:179,954,773–180,114,875, 1 gene, copy number 7 (within-gene range 4–7): CEP350.
- chr1:180,117,140–180,566,523, 8 genes, copy number 7: AL390718.1, QSOX1, LHX4, ACBD6, VDAC1P4, MIR3121, OVAAL, Y_RNA.
- chr2:196,763,035–198,772,356, 31 genes, copy number 7 (within-gene range 6–7): GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL, PLCL1, AC011997.2, AC020719.1, LINC01923, AC019330.1.
- chr2:199,608,068–199,750,341, 2 genes, copy number 8 (within-gene range 3–8): LINC01877, SEPHS1P6.
- chr2:202,634,969–204,507,672, 35 genes, copy number 7 (within-gene range 3–7): FAM117B, ICA1L, AC098831.1, KRT8P15, WDR12, CARF, KRT8P52, AC010900.1, NBEAL1, RPL7P14, AC023271.1, AC023271.2, RPL23AP36, RPL12P16, CYP20A1, RN7SL670P, MRPL50P2, ABI2, AC080075.1, RAPH1, AC125238.2, AC125238.1, CD28, KRT18P39, NPM1P33, RNU6-474P, CTLA4, ICOS, AC009965.2, AC009965.1, AC009498.1, DSTNP5, AC106901.1, AC016903.1, AC016903.2.
- chr2:204,668,863–204,678,698, 1 gene, copy number 7: AC007736.1.
- chr12:6,873,569–42,024,329, 705 genes, copy number 8–10 (within-gene range 3–10) (broad region; genes not listed).
- chr12:42,157,104–42,686,701, 18 genes, copy number 10: YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21.
- chr17:17,616,043–22,706,703, 265 genes, copy number 7–14 (broad region; genes not listed).
- chr17:39,566,915–41,734,644, 149 genes, copy number 8–33 (broad region; genes not listed).
- chr17:62,627,670–62,841,645, 8 genes, copy number 7–8 (within-gene range 4–8): MRC2, AC080038.3, RNU6-446P, AC005821.1, MARCHF10, AC005821.2, MARCHF10-DT, PRELID3BP3.
- chr20:44,966,479–45,080,021, 1 gene, copy number 9 (within-gene range 4–9): STK4.
- chr20:45,091,214–45,176,544, 5 genes, copy number 9: KCNS1, WFDC5, WFDC12, AL049767.1, PI3.

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
